Somatic mutation profile of tumor specimen TCGA-FU-A3TX-01A (aliquot TCGA-FU-A3TX-01A-11D-A22X-09) from TCGA case TCGA-FU-A3TX, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G3; Age at diagnosis: 78.9 years (28,825 days).
Specimen TCGA-FU-A3TX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e855c2c5-6b31-4ec2-bc20-4b84a3960a83.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FU-A3TX-10A (Blood Derived Normal), aliquot TCGA-FU-A3TX-10A-01D-A22X-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e58ad21-474c-4108-b2c1-0a4e40ecaa7c

The open-access MAF lists 63 somatic variants for this specimen: 48 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 14, Nonsense Mutation 4, Splice Region 2, Frame Shift Ins 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP8B1 | c.2854C>T p.R952* | Nonsense Mutation (SNP) | VAF 11/70 reads (16%) | catalogued as rs765889649, CM043830, COSV52178178; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CREBBP | c.3779+1G>A p.X1260_splice | Splice Site (SNP) | VAF 27/42 reads (64%) | catalogued as rs587783483, COSV52116972, COSV52125768, COSV52132996; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HUWE1 | c.12037C>T p.R4013W | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs121918525, CM081659, COSV53355787; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADAMTS20 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as rs776875165, COSV67135306; called by muse, mutect2, varscan2
- ARHGAP35 | c.2035G>T p.E679* | Nonsense Mutation (SNP) | VAF 15/32 reads (47%) | catalogued as COSV68333454; called by muse, mutect2, varscan2
- BRCA1 | c.4418C>A p.S1473Y | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV100523135, COSV58790529; called by muse, mutect2, varscan2
- BRCC3 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.876); catalogued as COSV57463305; called by muse, mutect2, varscan2
- CD151 | c.188T>G p.I63S | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.643); catalogued as COSV58990477; called by muse, mutect2, varscan2
- COL19A1 | c.1730G>T p.G577V | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1266313478, COSV59579518, COSV59585179; called by muse, mutect2, varscan2
- DHX57 | c.2129A>T p.D710V | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as rs776952163, COSV54888249; called by muse, mutect2, varscan2
- EXOC6B | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55563646; called by muse, mutect2, varscan2
- GPR179 | c.2734G>A p.V912M (on ENST00000621958; = p.V911M on NM_001004334.4) | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs201772198; called by muse, mutect2, varscan2
- GSPT1 | c.1108G>A p.E370K (on ENST00000420576 / NM_001130007.2; = p.E508K on NM_002094.4) | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV70452859; called by muse, mutect2, varscan2
- HEATR6 | c.1138G>C p.D380H | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as COSV51747355; called by muse, mutect2, varscan2
- HNF4A | c.388G>A p.V130I | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.134); catalogued as rs377476335, CM022020, COSV57384952; called by muse, mutect2, varscan2
- IGSF10 | c.1579C>T p.R527W | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372867906; called by muse, mutect2, varscan2
- INTS5 | c.1269G>C p.Q423H | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV57952631; called by muse, mutect2, varscan2
- ITGA3 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs778130201, COSV50322852; called by muse, mutect2, varscan2
- KCNH4 | c.2088C>T p.G696= | Splice Region (SNP) | VAF 19/26 reads (73%) | catalogued as COSV52919626; called by muse, mutect2, varscan2
- KDM6B | c.4667G>T p.R1556L | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.508); catalogued as COSV54684182, COSV54687792; called by muse, mutect2, varscan2
- LIG4 | c.2602G>A p.D868N | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV63596893, COSV63597587; called by muse, mutect2, varscan2
- LRP1 | c.2252A>G p.H751R | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as COSV54518675; called by muse, mutect2, varscan2
- LRRC10 | c.640C>G p.L214V | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV64060547; called by muse, mutect2, varscan2
- MAGEC1 | c.2839C>G p.P947A | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs763285093, COSV53567836, COSV53577256; called by muse, mutect2, varscan2
- MST1R | c.3436C>G p.L1146V | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV56565508; called by muse, mutect2, varscan2
- NR3C2 | c.2799C>T p.D933= | Splice Region (SNP) | VAF 44/59 reads (75%) | catalogued as rs371422334; called by muse, mutect2, varscan2
- NR3C2 | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.601); catalogued as COSV60995727; called by muse, mutect2, varscan2
- NXPE3 | c.889G>C p.D297H | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.711); catalogued as COSV56291139; called by muse, mutect2, varscan2
- ODF1 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs756865366, COSV53432294; called by muse, mutect2
- PCDHA2 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1554119963, COSV65369813; called by muse, mutect2
- PCDHA6 | c.1925C>G p.S642C | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); catalogued as COSV65342335, COSV65343616; called by muse, mutect2, varscan2
- PCSK7 | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1363291761, COSV58008506; called by muse, mutect2, varscan2
- PLXNB2 | c.2002C>T p.Q668* | Nonsense Mutation (SNP) | VAF 10/29 reads (34%) | catalogued as COSV63783237; called by muse, mutect2, varscan2
- PRPF19 | c.1041G>C p.E347D | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as rs1183773966, COSV57128629, COSV57129170; called by muse, mutect2, varscan2
- PTGER3 | c.630C>G p.I210M | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60694576; called by muse, mutect2, varscan2
- SEC16A | c.5921C>T p.P1974L | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV51534400; called by muse, mutect2, varscan2
- SESN3 | c.128T>G p.F43C | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53586232; called by muse, mutect2, varscan2
- SLC24A1 | c.1964G>A p.R655Q | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0.297); catalogued as rs201960929, COSV99977962; called by muse, mutect2, varscan2
- SPTA1 | c.2671C>T p.R891* | Nonsense Mutation (SNP) | VAF 28/44 reads (64%) | catalogued as rs755630903, CM148356, COSV63749670; called by muse, mutect2, varscan2
- TAF8 | c.728C>T p.S243L | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs752586050, COSV65896570; called by muse, mutect2, varscan2
- TMC2 | c.2665C>G p.Q889E | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV62655970, COSV62657556; called by muse, mutect2
- TSPEAR | c.1789G>T p.D597Y | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1303947217, COSV59970940; called by muse, mutect2, varscan2
- UNC13B | c.1147G>C p.V383L | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.956); catalogued as COSV65936775, COSV65938242; called by muse, mutect2, varscan2
- WARS2 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as COSV52480628; called by muse, mutect2, varscan2
- ZNF160 | c.2372G>A p.C791Y | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs757799835, COSV62000330; called by muse, mutect2, varscan2
- ZNF160 | c.638A>G p.N213S | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV62000333; called by muse, mutect2, varscan2
- ZNF550 | c.362C>T p.S121L | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.072); catalogued as rs767802802, COSV100286325; called by muse, mutect2, varscan2
- PTK2B | c.1788dup p.I597Hfs*2 | Frame Shift Ins (INS) | VAF 6/26 reads (23%) | called by mutect2, pindel, varscan2
- CSF2 | c.12G>A p.Q4= | Silent (SNP) | VAF 45/78 reads (58%) | catalogued as COSV51522657; called by muse, mutect2, varscan2
- DNAH9 | c.8334C>A p.T2778= | Silent (SNP) | VAF 31/98 reads (32%) | catalogued as COSV52362712; called by muse, mutect2, varscan2
- DNAH9 | c.10815C>T p.L3605= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as COSV52362725; called by muse, mutect2
- IQSEC3 | c.471G>A p.P157= | Silent (SNP) | VAF 18/183 reads (10%) | catalogued as rs782400831, COSV58287722; called by muse, mutect2, varscan2
- KCTD14 | c.288G>A p.G96= | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as COSV62001787; called by muse, mutect2, varscan2
- NAA11 | c.15C>T p.N5= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as rs745662845, COSV54515210; called by muse, mutect2, varscan2
- OR4D1 | c.441C>T p.A147= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as rs372813872; called by muse, varscan2
- PDE4DIP | c.4329G>A p.Q1443= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV57712018; called by muse, mutect2, varscan2
- SFMBT1 | c.1035C>T p.I345= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as COSV56255515; called by muse, mutect2, varscan2
- SLC5A4 | c.597G>A p.S199= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs142506993; called by muse, mutect2, varscan2
- TAPBP | c.456C>T p.I152= | Silent (SNP) | VAF 45/83 reads (54%) | catalogued as COSV101418475; called by muse, mutect2, varscan2
- TRIM71 | c.939C>T p.Y313= | Silent (SNP) | VAF 33/78 reads (42%) | catalogued as COSV67471935; called by muse, mutect2, varscan2
- TRPM3 | c.1743C>T p.G581= (on ENST00000357533 / NM_001366142.2; = p.G414= on NM_020952.6) | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as COSV62596456; called by muse, mutect2, varscan2
- WDR47 | c.2709C>T p.F903= (on ENST00000369962 / NM_001142551.2; = p.F904= on NM_014969.5) | Silent (SNP) | VAF 31/97 reads (32%) | catalogued as COSV63058854; called by muse, mutect2, varscan2
- CREM | c.121-8104_121-8103del | Intron (DEL) | VAF 74/120 reads (62%) | called by mutect2, varscan2
